MMRF case MMRF_2245 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/251a82ec-0b29-4652-911d-5f07ee5a7ec3

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 77 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 77.9 years (28,467 days); ISS stage: II; Days to last known disease status: 91 days; Days to last follow up: 91 days.
   Treatment given: Therapeutic agents: Bortezomib + Melphalan + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Follow-up (2 entries)
- Days to follow up: -1 day; ECOG performance status: 4.
- Follow-up contact recording only the day: day 91.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Lactate Dehydrogenase 2.15 µkat/L.
- Calcium 2.41 mmol/L.
- Leukocytes 6.7 ×10⁹/L.
- Immunoglobulin M 0.248 g/L.
- Blood Urea Nitrogen 5.96 mmol/L.
- Serum Free Immunoglobulin Light Chain, Kappa 89.7 mg/dL.
- Serum Free Immunoglobulin Light Chain, Lambda 0.557 mg/dL.
- Immunoglobulin A 1.29 g/L.
- Albumin 27.9 g/L.
- Platelets 157 ×10⁹/L.
- Beta 2 Microglobulin 2.37 µg/mL.
- C-Reactive Protein 1.57 mg/dL.
- Absolute Neutrophil 3.9 ×10⁹/L.
- Glucose 4.84 mmol/L.
- M Protein 2.5 g/dL.
- Immunoglobulin G 26.5 g/L.
- Hemoglobin 7.01 mmol/L.
- Creatinine 46 µmol/L.
- Total Protein 7.35 g/dL.

Other clinical attributes
- Day -1: Weight: 80 kg; Height: 160 cm.

Biospecimens (2 samples)
- Sample MMRF_2245_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -1 day.
- Sample MMRF_2245_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -1 day.
